Somatic mutation profile of tumor specimen TCGA-NA-A4QW-01A (aliquot TCGA-NA-A4QW-01A-11D-A28R-08) from TCGA case TCGA-NA-A4QW, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Corpus uteri; FIGO stage: Stage IIA; Age at diagnosis: 61.8 years (22,588 days).
Specimen TCGA-NA-A4QW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ef973f0-01e1-4cbd-8aa4-8db992e1df19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NA-A4QW-10A (Blood Derived Normal), aliquot TCGA-NA-A4QW-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc8012d8-fe5c-4e9d-a2f8-962492f5bb6b

The open-access MAF lists 60 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 40, Silent 14, Frame Shift Del 3, Splice Region 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 95/108 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1057519947, COSV59042211, COSV59042295; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 38/44 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AL441992.2 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 50/57 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1488368378; called by muse, mutect2, varscan2
- ATP4A | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs769990049, COSV52866484, COSV99382287; called by muse, mutect2, varscan2
- ATRN | c.3903G>C p.W1301C | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53524621; called by muse, mutect2, varscan2
- CKM | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs751425404; called by muse, mutect2, varscan2
- DHPS | c.147C>G p.F49L | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52951591, COSV52951708, COSV52952106; called by muse, mutect2, varscan2
- DIP2A | c.2077C>A p.L693M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59486719; called by muse, mutect2
- DOP1A | c.5591G>A p.R1864H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs367662678; called by muse, varscan2
- DPP10 | c.1795T>A p.F599I | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as COSV59707582; called by muse, mutect2, varscan2
- DYNC1H1 | c.11863G>A p.E3955K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs767837334; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPAT4 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 125/176 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs779520353, COSV67840355; called by muse, mutect2, varscan2
- ITPKB | c.2454A>G p.K818= | Splice Region (SNP) | VAF 17/56 reads (30%) | catalogued as rs552071294; called by muse, mutect2, varscan2
- MTMR6 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs373972921, COSV67808996; called by muse, mutect2, varscan2
- OR2G6 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs1399991357; called by muse, mutect2, varscan2
- PCDHGA11 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs762959766, COSV54037943; called by mutect2, varscan2
- POLR2A | c.4079A>G p.N1360S | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769104202; called by muse, mutect2, varscan2
- SERPINB10 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs201800135, COSV53072590; called by muse, mutect2, varscan2
- TEX10 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.73); catalogued as rs774262520, COSV66519771; called by muse, mutect2, varscan2
- TLN2 | c.189G>T p.W63C | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100168639; called by muse, mutect2, varscan2
- TNRC18 | c.8183C>T p.A2728V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs569812690; called by muse, mutect2, varscan2
- TUT7 | c.3004G>T p.D1002Y | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99463151; called by muse, mutect2, varscan2
- XYLT2 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated (0.99); PolyPhen benign (0.048); catalogued as rs148860176, COSV99190758; called by muse, mutect2, varscan2
- ZFP14 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV54205555; called by muse, mutect2, varscan2
- ZNF781 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 132/235 reads (56%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs772286028, COSV62201701; called by muse, mutect2, varscan2
- ARCN1 | c.424_426del p.K142del | In Frame Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel
- B4GALNT3 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNTNAP3 | c.1972G>C p.A658P | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.258); called by muse, varscan2
- DENND4C | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- DUSP22 | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FAM135B | c.3892C>A p.Q1298K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- FAM20A | c.813-5_824del p.X271_splice | Splice Site (DEL) | VAF 36/77 reads (47%) | called by mutect2, pindel, varscan2
- HIGD2A | c.175_181del p.A59Pfs*18 | Frame Shift Del (DEL) | VAF 85/229 reads (37%) | called by mutect2, pindel, varscan2
- HLA-B | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); called by muse, varscan2
- MYCBP2 | c.2889C>G p.N963K (on ENST00000357337; = p.N1001K on NM_015057.5) | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NCK1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OTUD7B | c.1371G>T p.E457D | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ROS1 | c.2885C>G p.A962G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SCUBE1 | c.414_426del p.Y139Afs*22 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- SLC10A2 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SPHKAP | c.4456C>T p.L1486F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TGM6 | c.1797G>T p.E599D | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TTLL5 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- TXN2 | c.288_290delinsTA p.G97Sfs*4 | Frame Shift Del (DEL) | VAF 48/182 reads (26%) | called by pindel, varscan2*
- UBR4 | c.3907G>C p.D1303H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ZNF654 | c.3157C>T p.P1053S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH9 | c.1965C>T p.N655= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as COSV99143532; called by muse, mutect2, varscan2
- DCXR | c.262C>T p.L88= | Silent (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- GBP5 | c.903C>T p.A301= | Silent (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- H2BC7 | c.282G>A p.E94= | Silent (SNP) | VAF 74/202 reads (37%) | catalogued as rs1036087644, COSV100587193; called by muse, mutect2, varscan2
- HIPK1 | c.984C>A p.R328= | Silent (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- IGF2BP3 | c.447G>A p.L149= | Silent (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- MAN2C1 | c.1374C>G p.L458= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as rs1289677361, COSV51244933; called by muse, mutect2, varscan2
- NUP43 | c.84C>T p.T28= | Silent (SNP) | VAF 98/236 reads (42%) | called by muse, mutect2, varscan2
- OR4K14 | c.195G>A p.G65= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100520448, COSV59293454; called by muse, mutect2, varscan2
- PPM1E | c.1353C>T p.S451= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs140315231; called by muse, mutect2, varscan2
- RPL3L | c.984C>T p.N328= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs770166648, COSV51906948; called by muse, mutect2, varscan2
- SLC16A12 | c.534C>T p.I178= | Silent (SNP) | VAF 23/177 reads (13%) | catalogued as rs192441993, COSV57948854; called by muse, mutect2, varscan2
- SUMF2 | c.291C>G p.V97= (on ENST00000652303; = p.V78= on NM_015411.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- TRIML2 | c.432G>A p.A144= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as rs141580546, COSV58715860; called by muse, mutect2, varscan2
